Somatic mutation profile of tumor specimen TCGA-G4-6627-01A (aliquot TCGA-G4-6627-01A-11D-2188-10) from TCGA case TCGA-G4-6627, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-G4-6627-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b487a46c-f229-41e6-81f8-c96fca365941.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6627-10A (Blood Derived Normal), aliquot TCGA-G4-6627-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/538c82ed-8672-4112-aa51-9623075c099c

The open-access MAF lists 91 somatic variants for this specimen: 71 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 18, Nonsense Mutation 5, Frame Shift Ins 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2
- EVC2 | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 10/111 reads (9%) | catalogued as rs781623802, COSV60391137; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 21/176 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 28/351 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABI3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs774034002, COSV56800665; called by muse, mutect2, varscan2
- ADGRL3 | c.2410G>T p.G804C (on ENST00000506720 / NM_001322402.2; = p.G736C on NM_015236.6) | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV72231733; called by muse, mutect2
- AMMECR1L | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55761519; called by muse, mutect2, varscan2
- APC | c.3964delinsCC p.E1322Pfs*10 | Frame Shift Ins (INS) | VAF 23/162 reads (14%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by mutect2*, pindel, varscan2*
- APOE | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52986441; called by muse, mutect2, varscan2
- ATG4C | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100508573; called by muse, mutect2
- CCDC6 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1370296808, COSV99569864; called by muse, mutect2
- CCDC60 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.392); catalogued as COSV100555704; called by muse, mutect2, varscan2
- CDH23 | c.2975C>T p.T992M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs765270590, COSV54925740; called by muse, mutect2
- CDK10 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.248); catalogued as COSV100450969; called by muse, mutect2
- COL20A1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs374818195; called by muse, mutect2, varscan2
- CPXM1 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013837; called by muse, mutect2, varscan2
- CTNND2 | c.3190G>A p.V1064M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142866396, COSV58872932, COSV58922522; called by muse, mutect2, varscan2
- CYP4B1 | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99597497; called by muse, mutect2, varscan2
- DMD | c.7225G>C p.E2409Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV58930579, COSV58945816; called by muse, mutect2, varscan2
- DROSHA | c.3719T>C p.F1240S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100757821; called by muse, mutect2, varscan2
- ENSA | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 23/212 reads (11%) | catalogued as COSV99651440; called by muse, mutect2, varscan2
- ERBB4 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201152419, COSV53517176; called by muse, mutect2, varscan2
- ESM1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs201100866; called by muse, mutect2, varscan2
- FAF1 | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV100876189; called by muse, mutect2, varscan2
- FIBCD1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs372273375, COSV99447534; called by mutect2, varscan2
- GEM | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV99891632; called by muse, mutect2
- GRIA1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs750421563, COSV53588586; called by muse, mutect2, varscan2
- GRIK5 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as rs201962794; called by muse, mutect2
- HERC2 | c.9136G>A p.V3046M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs202126440, COSV99876720; called by muse, mutect2, varscan2
- INPP1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59417294; called by muse, mutect2
- INTS5 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100399808; called by muse, mutect2
- ITGAV | c.2627C>T p.T876M | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); catalogued as rs368269954; called by muse, mutect2, varscan2
- KCND2 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as rs1411568642, COSV58570334; called by muse, mutect2, varscan2
- KERA | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV99899588; called by muse, mutect2
- KIRREL3 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); catalogued as COSV101585885; called by muse, mutect2, varscan2
- KLK2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100320057; called by muse, mutect2
- KTN1 | c.2961G>T p.Q987H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101255448; called by muse, mutect2, varscan2
- LCE1C | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.101); catalogued as rs756237878, COSV100908485; called by muse, mutect2, varscan2
- LILRB1 | c.1683G>T p.E561D (on ENST00000427581; = p.E511D on NM_006669.6) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV100207892; called by muse, mutect2, varscan2
- LZTR1 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs750902731, COSV53151340; called by muse, mutect2, varscan2
- MAGEC1 | c.2655G>T p.L885F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs769947583, COSV99596519; called by muse, mutect2, varscan2
- MAP3K1 | c.3729G>T p.W1243C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101267111; called by muse, mutect2
- MUC16 | c.16883C>G p.T5628S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV67501787; called by muse, mutect2
- NELL1 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266049620, COSV100125224; called by muse, mutect2, varscan2
- NIPBL | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV99240615; called by muse, mutect2, varscan2
- OR1C1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs373256453, COSV68715606; called by muse, mutect2, varscan2
- OR5D14 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100162547, COSV100162612; called by muse, mutect2
- OR5K2 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs781388183, COSV101415985; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDH17 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64979460; called by muse, mutect2, varscan2
- PDE1C | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs267601486, COSV58516968, COSV58527985; called by muse, mutect2, varscan2
- PGM1 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs139155697, COSV100936602; called by muse, mutect2, varscan2
- RSPO1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756170881, COSV62973766; called by muse, mutect2, varscan2
- SACS | c.7079C>A p.S2360Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV101207729; called by muse, mutect2, varscan2
- SELENOH | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99560343; called by muse, mutect2
- SLC4A9 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs187685311; called by muse, mutect2
- SLC7A11 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs554325259, COSV54935160; called by muse, mutect2, varscan2
- SLFNL1 | c.1040G>C p.R347P | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100263183; called by mutect2, varscan2
- TET1 | c.5918A>G p.E1973G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101018897; called by muse, mutect2
- TNIP3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs986155957, COSV50257639; called by muse, mutect2
- TNKS | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1024809439, COSV100127877; called by muse, mutect2
- TRIP11 | c.5555A>G p.Q1852R | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs1006565011, COSV99971195; called by muse, mutect2, varscan2
- TSPAN2 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as rs777331815, COSV65689416; called by muse, mutect2, varscan2
- TTN | c.80344C>T p.R26782* (on ENST00000591111; = p.R19358* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 31/224 reads (14%) | catalogued as rs769664554, COSV60016577; called by muse, mutect2, varscan2
- TTN | c.16101G>T p.K5367N (on ENST00000591111; = p.K4440N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | PolyPhen benign (0.361); catalogued as COSV100630187; called by muse, mutect2
- UBE2O | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV60067353; called by muse, mutect2, varscan2
- VWF | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs61748466, CM030088, COSV54618410; ClinVar: not provided; called by muse, mutect2, varscan2
- WIZ | c.3967C>T p.R1323W (on ENST00000673675 / NM_001371589.1; = p.R228W on NM_021241.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs758406787, COSV54611747; called by muse, mutect2, varscan2
- WRNIP1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761279595, COSV101062810; called by muse, mutect2, varscan2
- ZNF99 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV101233969; called by muse, mutect2, varscan2
- APC | c.3963dup p.E1322Rfs*10 | Frame Shift Ins (INS) | VAF 20/128 reads (16%) | called by mutect2, varscan2
- ARHGAP6 | c.927T>G p.S309= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV100273565; called by muse, mutect2, varscan2
- CACNA1A | c.255C>T p.N85= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1285665891, COSV100802754; called by muse, mutect2
- DNAH9 | c.12000C>A p.G4000= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99308145; called by muse, mutect2, varscan2
- FAT3 | c.5433T>C p.L1811= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99971030; called by muse, mutect2
- FOXF1 | c.426C>A p.R142= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99296754; called by mutect2, varscan2
- FZD1 | c.1503C>T p.I501= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV55313149; called by muse, mutect2, varscan2
- GIMAP1 | c.684G>A p.A228= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1202671941, COSV56187236; called by muse, mutect2
- H3C7 | c.312C>T p.L104= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs773717476, COSV55100437, COSV99769275; called by muse, mutect2
- KRTAP12-2 | c.273G>A p.R91= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs372325865; called by muse, mutect2
- LINGO1 | c.1014C>T p.R338= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs770463478, COSV62438452; called by muse, mutect2, varscan2
- MYH6 | c.2311C>T p.L771= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100676995; called by muse, mutect2, varscan2
- MYO5B | c.3753C>T p.H1251= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs548510364, COSV53222692; called by muse, mutect2, varscan2
- NDST4 | c.273C>T p.L91= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs1388696193, COSV52108678; called by muse, mutect2, varscan2
- PCDHA4 | c.1701G>T p.A567= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs556570330, COSV100793749; called by muse, mutect2
- SH3GL3 | c.462C>T p.I154= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs757389465, COSV61057935; called by muse, mutect2, varscan2
- SPI1 | c.465C>T p.P155= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1309529671, COSV99909261; called by muse, varscan2
- XRRA1 | c.216G>A p.K72= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV58500052; called by muse, mutect2
- ZNF7 | c.57G>A p.Q19= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as COSV100296147; called by muse, mutect2
- VPS11 | c.-963G>A | 5'UTR (SNP) | VAF 14/109 reads (13%) | catalogued as rs1404992268, COSV100333644, COSV100334007; called by muse, mutect2, varscan2
- Y_RNA | chr7:75512619 C>G | 3'Flank (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
